Gene-level copy-number profile of tumor specimen TCGA-EJ-A65B-01A from TCGA case TCGA-EJ-A65B, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.3 years (20,204 days).
Specimen TCGA-EJ-A65B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.de779a56-cb13-4592-a380-ac110c1b159f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-A65B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b23b860d-217d-4eb1-a64e-bfdf10390c62

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 8,003; copy number 2: 51,696; copy number 3: 48; copy number 4: 64.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-A65B-01A-12D-A30D-01): tumor purity 0.26, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
